Surgical pathology report (de-identified scan), TCGA case TCGA-DU-6404, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-6404-02B (Recurrent Tumor).

[page 1 of 3]
Surgical Pathology Report

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: (Age:) Location: Received:
Gender: F Acct: Reported:
Physician(s):
Phy Location:

Clinical History

year-old woman has PMH significant for anaplastic oligodendroglioma first diagnosed in Patient has undergone 5 additional craniotomies for tumor resection since, most recently in . The tumor appears to be of a neuroepithelial nature and has a spongioblastoma pattern. Currently there is focal recurrence and infiltration.

Operative Diagnoses

Operation / Specimen

- A: Brain, posterior encephalocele, biopsy
- B: Brain, superior encephalocele, biopsy
- C: Brain, posterior tumor, biopsy
- D: Brain, anterior tumor, biopsy

Pathologic Diagnosis

A, B, and C. Brain, posterior, superior, and posterior tumor, excision:

1. Malignant neuroepithelial (neuroectodermal) neoplasm, with focal neuronal differentiation (WHO IV).

2. MIB-1 proliferation index: 80%.

See Microscopy Description and Comment.

Comment

The specimen is portions of a poorly differentiated neoplasm of neuroepithelial (neuroectodermal) origin. The tumor has a predominant small cell, spindle cell pattern, with focal palisading (spongioblastoma polare-like). Immunophenotypically a majority of the tumor is undifferentiated. However, there are focal areas of neuronal differentiation; in these areas there is abundant deposition of reticulum fibers. The tumor has focal areas of necrosis with hemorrhage and suggestion of pseudopalisading. The neoplasm has very high mitotic activity and the MIB-1 cycling rate is around 80%.

At this point this malignant tumor of neuroectodermal origin is largely undifferentiated, but also has focal areas of neuronal differentiation with some reticulum formation (slight desmoplasia, "intermediate"). The MIB-1 proliferation index is very high.

Parts A, B, and C are portions of solid tumor. Part D is fragments of rarefied cerebral tissue with small nests of neoplastic tissue infiltrating mostly along vessels.

Electronically Signed Out

, Senior Staff Pathologist

Surgical Pathology

Page 2 of 4

Procedures/Addenda

ICD-O-3 recurrence #2
neuroectodermal tumor, NOS
9364/3
Site: brain, NOS C71.9

fw
2/12/15

[page 2 of 3]
MGMT Promoter Methylation**Date Ordered:** **Date Reported:****Interpretation**

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (A2)

H& E was examined and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit

from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of

DNA followed by real-time PCR amplification of methylated and unmethylated DNA sequences. The

analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors

such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the

detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

Electronically Signed Out

, Senior Staff Pathologist

Gross Description

A.

Brain, posterior encephalocele, biopsy

CONTAINER LABEL: posterior encephalocele.

FIXATIVE: Formalin. NO. PIECES: 1. SIZE/VOL: 2 x 1.2 x 0.9 cm, 1.38 gram, bisected. CASSETTES: 1, 2

B.

Brain, superior encephalocele, biopsy

CONTAINER LABEL: superior encephalocele.

FIXATIVE: Formalin. NO. PIECES: 1. SIZE/VOL: 1 x 0.9 x 0.8 cm, 0.325 gram, bisected CASSETTES: 1

C.

Brain, posterior tumor, biopsy

CONTAINER LABEL: posterior tumor.

FIXATIVE: Formalin. NO. PIECES: 1. SIZE/VOL: 2 x 1.4 x 1 cm, 1.18 gram, bisected CASSETTES: 1, 2

D.

Brain, anterior tumor, biopsy:

CONTAINER LABEL: anterior tumor.

FIXATIVE: Formalin. NO. PIECES: 1. SIZE/VOL: 2.5 x 1.1 x 1 cm, 1.47 gram, bisected CASSETTES: 1, 2,

Surgical Pathology

Page 3 of 4

Microscopic Description

[page 3 of 3]
IMMUNOHISTOCHEMISTRY: The tumor cells overall are GFAP, S100, NeuN, and EMA negative. In focal areas there is background and perinuclear synaptophysin reactivity, and in the same areas there is prominent background and perinuclear NFP positivity. The NeuN demonstrates normal native neurons. With the MIB-1 about 80% of neoplastic cells are positive.

SPECIAL STAIN: Focally there are zones of prominent intercellular reticulin deposition demonstrated by the Snook's reticulum stain. These are the synaptophysin and NFP positive areas.

ICD-9(s): 191.9 191.9

Billing Fee Code(s): A:

B:

C:

D:

MGMT:

Histo Data

Part A: Brain, posterior encephalocele, biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

H&E x 1 1

Rct 1 H&E x 1 1

mGFAP-DA x 1 2

H&E x 1 2

MGMT-curls x 1 2

MIB1-DA x 1 2

Rct 1 H&E x 1 2

TTF1-DA x 1 2

Part B: Brain, superior encephalocele, biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

H&E x 1 1

Part C: Brain, posterior tumor, biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

mGFAP-DA x 1 1

H&E x 1 1

CD99-DA x 1 1

MAP2 x 1 1

NF2F11 x 1 1

Retic x 1 1

Synap-DA x 1 1

M Trich x 1 1

Vim-DA x 1 1

H&E x 1 2

Part D: Brain, anterior tumor, biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

EMA-DA x 1 1

mGFAP-DA x 1 1

Surgical Pathology

Page 4 of 4

H&E x 1 1

MIB1-DA x 1 1

MAP2 c x 1 1

NeuN x 1 1

NF2F11 x 1 1

Retic x 1 1

S100-DA x 1 1

Synap-DA x 1 1

Source: NCI Genomic Data Commons file 2e0860b8-04f8-4dcd-87e2-875b08b8f25b (TCGA-DU-6404.4A27AEBA-B999-4F7F-B28F-CCC5AD367BA2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).